Gene-level copy-number profile of tumor specimen TCGA-FI-A2EY-01A from TCGA case TCGA-FI-A2EY, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 63.1 years (23,042 days).
Specimen TCGA-FI-A2EY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.addcd76a-d0a9-4c04-828c-fbb391be6f0d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FI-A2EY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/38d19618-83f5-4f7f-8c4e-7dd15bbda2d1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 76; copy number 1: 5,662; copy number 2: 22,325; copy number 3: 19,720; copy number 4: 8,939; copy number 5: 2,472; copy number 6: 167; copy number 7: 140; copy number 8: 64; copy number 9: 79; copy number 11: 93; copy number 12: 38; copy number 16: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FI-A2EY-01A-12D-A18N-01): tumor purity 0.89, ploidy 2.74, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 76 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:40,191,053–42,707,335, 48 genes (within-gene range 0–3): RHOH, AC095057.2, LINC02265, CHRNA9, RNU7-74P, RBM47, AC098869.2, AC098869.1, MIR4802, AC131953.2, NSUN7, ARL4AP2, APBB2, AC131953.1, Y_RNA, RNA5SP160, RNU6-836P, RNU6-1195P, UCHL1-AS1, UCHL1, Y_RNA, LIMCH1, RPL12P20, AC108050.1, AC105389.2, OR5M14P, PHOX2B, PHOX2B-AS1, AC105389.1, RNU1-49P, HMGB1P28, LINC00682, AC108210.1, AC108210.2, TMEM33, DCAF4L1, AC106052.1, SLC30A9, ATP1B1P1, BEND4, AC111006.1, AC024022.1, SHISA3, ATP8A1, RPS7P7, CCNL2P1, AC096734.2, AC096734.1.
- chr4:43,457,527–44,025,516, 8 genes (within-gene range 0–1): LINC02383, AC114774.1, RN7SL691P, AC080132.1, RN7SL193P, NDUFB4P12, AC114757.1, LINC02475.
- chr12:42,456,757–42,590,355, 1 gene (within-gene range 0–2): PRICKLE1.
- chr12:42,485,353–43,758,793, 19 genes: AC079600.3, LINC02402, AC079600.2, AC079600.1, LINC02451, RPS27P21, LINC02450, AC068802.1, AC012038.2, AC012038.1, MRPS36P5, LINC02461, ADAMTS20, AC090525.1, AC090525.2, AC090525.3, EEF1A1P17, PUS7L, AC093012.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,088 genes in 37 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:158,127,287–164,980,137, 232 genes, copy number 5 (broad region; genes not listed).
- chr1:173,183,731–173,903,549, 19 genes, copy number 6: TNFSF4, AL645568.2, AL645568.1, PRDX6-AS1, PRDX6, SLC9C2, AL139142.1, AL139142.2, ANKRD45, TEX50, KLHL20, BX248409.1, RN7SKP160, CENPL, Y_RNA, DARS2, GAS5, GAS5-AS1, ZBTB37.
- chr1:236,110,061–239,974,245, 50 genes, copy number 5: AL122018.1, AL122018.2, GPR137B, ERO1B, RNU2-70P, AL450309.1, EDARADD, ENO1P1, LGALS8, LGALS8-AS1, AL359921.2, AL359921.1, HEATR1, ACTN2, MTR, RPSAP21, RPL35P1, MT1HL1, AL359259.1, RYR2, RN7SKP195, MIR4428, AL442065.1, AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9, AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32, MIPEPP2, AL583825.1, AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2, CHRM3-AS1, AL356361.2, AL356361.1.
- chr2:78,412,793–83,657,842, 47 genes, copy number 5: CYCSP6, AC064872.1, AC092660.1, AC092604.1, RNU6-827P, RNU6-812P, REG3G, REG1B, REG1A, REG1CP, REG3A, AC011754.1, CTNNA2, AC011754.2, CTNNA2-AS1, AC010975.1, GNA13P1, RNU6-561P, MIR4264, MIR8080, AC016716.1, RBM7P1, LRRTM1, AC008067.1, AC012355.1, ANKRD11P1, CHMP4AP1, LINC01815, RNA5SP99, AC013262.1, RN7SL201P, AC079896.1, LYARP1, RNU6-685P, Y_RNA, AC010105.1, RBX1P1, MTND4P25, MTND5P27, MTND6P7, MTCYBP7, AC098817.1, DHFRP3, AC138623.1, LINC01809, RPL37P10, RNU6-1312P.
- chr3:163,026,396–198,222,513, 643 genes, copy number 5 (broad region; genes not listed).
- chr4:20,728,606–21,948,772, 1 gene, copy number 6 (within-gene range 4–6): KCNIP4.
- chr4:21,304,468–22,611,063, 12 genes, copy number 5–6: AC110296.1, MIR7978, AC096576.7, AC096576.3, AC096576.1, AC096576.2, KCNIP4-IT1, AC096719.1, RNU6-420P, ADGRA3, AC098583.1, AC098583.2.
- chr4:44,533,615–46,510,194, 18 genes, copy number 5: AC093852.1, YIPF7, GUF1, GNPDA2, AC096586.2, AC096586.1, AC093755.1, PRDX4P1, AC108467.2, AC108467.1, THAP12P9, AC108043.1, RNU6-931P, RN7SKP199, GABRG1, AC104072.1, GABRA2, AC095060.1.
- chr4:57,030,773–58,118,070, 14 genes, copy number 6: IGFBP7, UBE2CP3, IGFBP7-AS1, AC111197.1, AC105390.1, RPS26P24, LINC02380, AC013724.1, AC107396.1, AC093725.2, AC093725.1, AC104790.1, SRIP1, AC096725.1.
- chr5:1,798,385–4,147,429, 30 genes, copy number 5: MRPL36, NDUFS6, AC025183.1, LINC02116, AC025183.2, IRX4, IRX4-AS1, CTD-2194D22.4, AC126768.3, AC124852.1, AC126768.1, AC126768.2, Y_RNA, AC092266.1, LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1, AC094105.2, LINC01377, LINC01019, LINC02162, LINC01017, IRX1, AC016595.1, AC025773.1, AC025187.1, LINC02063.
- chr5:6,134,303–10,082,772, 84 genes, copy number 5–8 (broad region; genes not listed).
- chr5:28,548,135–28,809,291, 3 genes, copy number 8 (within-gene range 4–8): AC008825.1, AC109472.1, RNU6-909P.
- chr5:40,415,137–45,895,970, 89 genes, copy number 5–8 (broad region; genes not listed).
- chr6:167,607–15,113,221, 276 genes, copy number 5–7 (broad region; genes not listed).
- chr6:60,719,222–68,329,899, 55 genes, copy number 5: GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1, SLC25A51P1, ADH5P4, NUFIP1P1, AL450336.1, RNU7-66P, AL591004.1, AL365503.1, RNA5SP208, RNU6-280P, Y_RNA, AL713998.1, AL713998.3, AL713998.4, AL713998.2, AL646090.2, AL646090.1, AL593844.1, LINC02549.
- chr6:77,343,557–85,167,749, 88 genes, copy number 7 (broad region; genes not listed).
- chr7:10,901,978–34,878,332, 384 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr7:48,846,426–53,574,555, 51 genes, copy number 5–6: AC004899.1, AC004899.2, GDI2P1, CDC14C, AC091730.1, DDX43P2, AC092448.1, AC093775.1, VWC2, ZPBP, GNL2P1, AC034148.1, SPATA48, AC020743.1, AC020743.2, AC020743.3, IKZF1, AC124014.1, RNU6-1091P, FIGNL1, DDC, DDC-AS1, GRB10, AC005153.1, AC004920.1, AC009296.1, AC004830.2, AC004830.1, COBL, RPL7L1P2, CICP17, AC012441.2, AC012441.1, AC005999.2, ROBO2P1, AC005999.1, RN7SL292P, AC006478.1, AC006478.2, AC079763.1, AC006320.1, AC006459.1, SGO1P2, AC074397.1, POM121L12, HAUS6P1, RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1.
- chr8:126,474,189–129,683,770, 41 genes, copy number 11–16 (within-gene range 3–16): AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686.
- chr10:116,056,925–117,831,244, 35 genes, copy number 5: GFRA1, AC012470.1, CCDC172, SNRPGP6, PNLIPRP3, HMGB3P8, RNU6-1090P, PNLIP, PNLIPP1, PNLIPRP1, PNLIPRP2, C10orf82, AC016825.1, HSPA12A, RPL5P27, ENO4, SHTN1, AC023283.1, AC012308.1, VAX1, MIR3663HG, MIR3663, RPL12P26, KCNK18, AL731557.1, SLC18A2, AL391988.1, PDZD8, AC005871.2, EMX2OS, EMX2, AC005871.1, AL356419.1, LINC02674, AL513324.1.
- chr11:99,020,949–100,358,885, 1 gene, copy number 5 (within-gene range 3–5): CNTN5.
- chr11:100,336,856–100,993,941, 6 genes, copy number 5: RPA2P3, RN7SL222P, PPIAP43, ARHGAP42-AS1, ARHGAP42, RN7SKP115.
- chr12:66,767–2,889,524, 71 genes, copy number 5 (broad region; genes not listed).
- chr12:2,885,819–2,886,329, 1 gene, copy number 5: AC005911.1.
- chr12:5,948,877–7,328,724, 89 genes, copy number 5 (broad region; genes not listed).
- chr12:18,080,869–19,108,183, 11 genes, copy number 7: RERGL, PIK3C2G, NDFIP1P1, AC092851.1, ZKSCAN7P1, PLCZ1, PSMC1P9, AC087242.1, CAPZA3, RPL7P6, MEF2BNBP1.
- chr12:19,147,074–19,176,589, 2 genes, copy number 7: AC092828.1, RN7SL459P.
- chr12:27,389,789–28,581,511, 31 genes, copy number 5 (within-gene range 4–5): ARNTL2-AS1, SMCO2, RARS1P1, PPFIBP1, AC087257.1, AC087257.2, AC009509.3, AC009509.1, REP15, AC009509.4, HMGB1P49, AC009509.2, MRPS35, Y_RNA, MANSC4, AC009511.2, KLHL42, AC009511.1, RN7SKP15, AC009511.3, AC008011.1, PTHLH, AC008011.2, CCDC91, AC022364.1, AC022364.2, AC022079.2, AC022079.1, RNU4-54P, RNA5SP355, AC084754.1.
- chr12:43,758,944–50,480,004, 214 genes, copy number 5 (within-gene range 0–5) (broad region; genes not listed).
- chr12:61,708,259–62,279,150, 1 gene, copy number 5 (within-gene range 3–5): TAFA2.
- chr12:62,021,570–64,162,217, 40 genes, copy number 5 (within-gene range 3–5): RPS3P6, AC078789.1, KLF17P1, USP15, MIR6125, RNU6-595P, Metazoa_SRP, MON2, AC079035.1, RNU6-399P, LINC01465, AC048341.1, MIRLET7I, AC048341.2, PPM1H, RPL32P26, GAPDHP44, RNU1-83P, Y_RNA, RPL14P1, AC078814.2, LDHAL6CP, AC078814.1, RSL24D1P5, AVPR1A, AC135584.1, HNRNPA1P69, AC026116.1, DPY19L2, AC084357.2, AC027667.1, AC084357.3, AC084357.1, RXYLT1, RXYLT1-AS1, PABPC1P4, SRGAP1, RPL36AP41, AC079866.2, AC079866.1.
- chr13:87,427,214–87,892,472, 8 genes, copy number 5 (within-gene range 2–5): MIR4500HG, AL355578.1, MIR4500, SLITRK5, AL445647.2, LINC00397, AL445647.1, TET1P1.
- chr17:36,064,272–41,213,237, 235 genes, copy number 5–12 (broad region; genes not listed).
- chr18:894,435–6,915,716, 108 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr18:27,335,968–27,595,164, 1 gene, copy number 5 (within-gene range 4–5): AC090403.1.
- chr18:27,418,884–30,780,424, 19 genes, copy number 5: RBM22P1, PA2G4P3, AC068408.2, AC090936.1, CDH2, AC110015.1, AC006249.1, AC090365.1, ARIH2P1, AC023932.1, RNU6-408P, AC105245.1, AC074237.1, AC117569.1, AC117569.2, AC115100.1, MIR302F, AC090506.1, AC090506.2.
- chr20:3,732,685–6,528,459, 78 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,241. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
